Surgical pathology report (de-identified scan), TCGA case TCGA-WC-A885, project TCGA-UVM (Uveal Melanoma), tissue source site MD Anderson, specimen TCGA-WC-A885-01A (Primary Tumor).

Accession:
Specimen Date/Time:

DIAGNOSIS

(A) RIGHT GLOBE:

(790%)

CHOROIDAL MELANOMA, spindle type, 12 base x 6 mm height.

SCLERAL INVASION PRESENT IN PERIVASCULAR PATTERN

Extraocular extension is not identified.

Vortex veins and optic nerve, negative for tumor.

See comment.

ICD O-3

Melanoma, spindle cell 8772/3

Site: Choroid C69.3

Q10 1/10/14

COMMENT

Mitoses are identified at 3 per 10 high power fields.

GROSS DESCRIPTION

(A) RIGHT GLOBE –an intact right globe (22 x 22 x 23 mm) has an unremarkable sclera and clear anterior chamber formed 10 x 11mm iris with round central pupil (4 mm diameter). The optic nerve is 11 mm in length. On transillumination a shadow present 10mm from the limbus and 6 mm from the optic nerve. The eye is opened fresh for tissue harvest per protocol. The vitreous is clear and a natural lens is in place. A dark black brown tumor corresponding to the shadow has a 12 x 12 mm base x 6 mm height. The sclera is grossly intact. The optic disc and ciliary body are uninvolved.

SECTION CODE: A1, external tissue of vortex veins; A2, optic nerve margin and portion of cornea/anterior chamber calotte with focal tumor; A4, calotte with tumor; A5, pupil-optic nerve section with tumor.

(B) RIGHT EYE ASPIRATE – a vial with fluid and potential flecks of tissue held at room temperature is inadequate for send testing. No further evaluation of this specimen. was notified.

BIOMARKER TESTING

The following material is selected for biomarker testing:

Primary Tumor Block: A5

CLINICAL HISTORY

Presumed uveal melanoma

SNOMED CODES

T-AA000, M-87203

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have no

Entire report and diagnosis completed by:

-----END OF REPORT-----

ICD-9 Discrepancy		✓
Reviewer Initials	Q10	10/7/13

Source: NCI Genomic Data Commons file 5a3ce3d8-5ad0-460d-b043-3ce1fe0f1afc (TCGA-WC-A885.1D5AEA80-D8C7-444F-BFB4-1B3822C8D17B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).